Somatic mutation profile of tumor specimen TCGA-06-6388-01A (aliquot TCGA-06-6388-01A-12D-1845-08) from TCGA case TCGA-06-6388, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.4 years (23,519 days).
Specimen TCGA-06-6388-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a00b5bc-7d64-4eda-a1a4-751c0ff0c80f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6388-10A (Blood Derived Normal), aliquot TCGA-06-6388-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a94d2da-c8fd-483a-a1d3-4887eee51f40

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 15, Splice Site 4, Nonsense Mutation 3, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOX9 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1555629169, COSV55422898; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.3244A>G p.S1082G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV65317696; called by muse, mutect2, varscan2
- ADGRL3 | c.269G>A p.R90H (on ENST00000506720 / NM_001322402.2; = p.R22H on NM_015236.6) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772186652, COSV72268570; called by muse, mutect2, varscan2
- ATRX | c.3054G>T p.K1018N | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs1184990999, COSV64879429; called by muse, mutect2, varscan2
- ENPP4 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.246); catalogued as COSV58089929; called by muse, mutect2, varscan2
- FBXO15 | c.949C>G p.H317D | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54048318; called by muse, mutect2, varscan2
- FLG2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs747766822, COSV66167219; called by muse, mutect2, varscan2
- FUT5 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs200537067, COSV53138574; called by muse, mutect2, varscan2
- IGLV3-25 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377042516; called by muse, mutect2, varscan2
- IL26 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs781449971, COSV57489954, COSV99970902; called by muse, mutect2, varscan2
- IL4R | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs911092896, COSV50167292; called by muse, mutect2, varscan2
- IRX6 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1263152225, COSV51860322; called by muse, mutect2, varscan2
- KCND3 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56188579; called by muse, mutect2, varscan2
- LNPEP | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51480890; called by muse, mutect2, varscan2
- MME | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 30/72 reads (42%) | catalogued as COSV64710191; called by muse, mutect2, varscan2
- NLGN3 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV62445037; called by muse, mutect2
- NLRP4 | c.1448T>A p.L483* | Nonsense Mutation (SNP) | VAF 37/204 reads (18%) | catalogued as COSV56721979; called by muse, mutect2, varscan2
- NPBWR2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs767389109, COSV63899978; called by muse, mutect2, varscan2
- OTOP3 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs372869932, COSV60914838; called by muse, mutect2, varscan2
- PIK3R1 | c.1937T>C p.F646S (on ENST00000521381 / NM_181523.3; = p.F376S on NM_181504.4) | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57138076; called by muse, varscan2
- PLD1 | c.2762G>C p.G921A | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV60573436; called by muse, mutect2, varscan2
- PPP2R5B | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51212884; called by muse, mutect2, varscan2
- RALGAPA2 | c.4228C>T p.H1410Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762053546, COSV52509488; called by muse, mutect2, varscan2
- RCBTB1 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV51636545; called by muse, mutect2, varscan2
- RYR2 | c.7341A>T p.K2447N | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63710223; called by muse, mutect2, varscan2
- RYR3 | c.1453G>T p.V485F | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66806409; called by muse, mutect2
- SDK1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs758245711, COSV67386071; called by muse, mutect2
- SLTM | c.2110C>G p.R704G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51057569; called by muse, mutect2, varscan2
- STAG2 | c.2445T>A p.Y815* | Nonsense Mutation (SNP) | VAF 77/225 reads (34%) | catalogued as COSV54371009; called by muse, mutect2, varscan2
- TGFA | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782577747, COSV54912877; called by muse, mutect2, varscan2
- TMEM17 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs561991904, COSV59023354; called by muse, mutect2, varscan2
- JAG1 | c.438_439+2del p.X146_splice | Splice Site (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- MAGEB3 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.677); called by muse, mutect2
- SNX32 | c.374+2dup p.X125_splice | Splice Site (INS) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- TRMT13 | c.261+2dup p.X87_splice | Splice Site (INS) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- ADRB1 | c.445C>T p.L149= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as COSV65168324; called by muse, mutect2, varscan2
- CFAP43 | c.2664G>A p.S888= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as rs776722704, COSV53376796; called by muse, mutect2, varscan2
- EPB41L3 | c.3126G>T p.T1042= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV59465949; called by muse, mutect2, varscan2
- FAT2 | c.5058C>T p.S1686= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs747670974, COSV55818132; called by muse, mutect2, varscan2
- HGF | c.474C>T p.H158= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs367553438; called by muse, mutect2, varscan2
- MAGED2 | c.1557C>T p.D519= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs775755120, COSV54499203; called by muse, mutect2, varscan2
- MSH4 | c.564T>C p.F188= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV54210689; called by muse, mutect2, varscan2
- NT5C1A | c.171C>T p.S57= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs775586267, COSV52496214; called by muse, mutect2, varscan2
- PDHA2 | c.93C>T p.D31= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs143281239, COSV54779791; called by muse, mutect2, varscan2
- PSG2 | c.789G>A p.A263= | Silent (SNP) | VAF 87/334 reads (26%) | catalogued as rs761048790, COSV61544869, COSV61545864; called by muse, mutect2, varscan2
- PSG4 | c.90G>A p.P30= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as rs533600298, COSV54932696; called by muse, mutect2, varscan2
- RAD51AP2 | c.3456C>T p.Y1152= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs746043981, COSV67587865; called by muse, mutect2, varscan2
- SAMD12 | c.222G>C p.V74= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV59056244; called by muse, mutect2, varscan2
- TNFRSF8 | c.753C>T p.D251= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs536842664, COSV55796217; called by muse, mutect2, varscan2
- WWC3 | c.3045C>T p.D1015= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs754124287, COSV66506875; called by muse, mutect2, varscan2
- HMGB1P1 | n.475_476del | RNA (DEL) | VAF 15/58 reads (26%) | called by pindel, varscan2
- TRPV2 | chr17:16441281 A>G | 3'Flank (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2
- ZNF833P | n.529G>A | RNA (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
